Somatic mutation profile of cancer-model specimen HCM-CSHL-0823-C34-85M (3D Organoid, passage 6; aliquot HCM-CSHL-0823-C34-85M-01D-A85L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0823-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 62.8 years (22,955 days).
Specimen HCM-CSHL-0823-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a5e127c-fb2f-4e4f-9c24-9b91c607e48f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0823-C34-10A (Blood Derived Normal), aliquot HCM-CSHL-0823-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69fc66b1-4fd4-4517-b5c6-11b8eb26f291

The open-access MAF lists 561 somatic variants for this specimen: 422 protein-altering or splice-affecting, 122 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 375, Silent 122, Nonsense Mutation 22, Frame Shift Del 14, Intron 9, In Frame Del 5, 5'UTR 4, Translation Start Site 2, Splice Site 2, 5'Flank 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 146/217 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- ABCA2 | c.3415G>A p.E1139K (on ENST00000614293; = p.E1109K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.207); catalogued as rs1052777052; called by muse, mutect2
- ABCA7 | c.4195G>T p.V1399L | Missense Mutation (SNP) | VAF 118/444 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs1429212010; called by muse, mutect2, varscan2
- ABCB1 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99711998; called by muse, mutect2, varscan2
- ADGRE1 | c.420del p.S140Rfs*71 | Frame Shift Del (DEL) | VAF 68/181 reads (38%) | catalogued as CM1514573; called by mutect2, pindel, varscan2
- AKAP8 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 134/598 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs1356111761; called by muse, mutect2, varscan2
- AKR1C1 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 92/552 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs138128200; called by muse, mutect2, varscan2
- ALOX5 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 186/362 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65553396; called by muse, mutect2, varscan2
- ALPP | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 240/443 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs148987850; called by muse, mutect2, varscan2
- ANKRD62 | c.2677C>A p.Q893K | Missense Mutation (SNP) | VAF 48/465 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1462129584; called by muse, mutect2, varscan2
- ARHGAP33 | c.3248G>C p.R1083T | Missense Mutation (SNP) | VAF 46/1002 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as rs747370383; called by muse, mutect2
- ARHGAP36 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 194/196 reads (99%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs182540216, COSV52264298; called by muse, mutect2, varscan2
- ARHGEF9 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM045635; called by muse, mutect2, varscan2
- ATP10A | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 252/418 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791626, COSV63516234; called by muse, mutect2, varscan2
- ATP6V1C2 | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1483048042; called by muse, mutect2, varscan2
- BBS9 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140198337; called by muse, mutect2, varscan2
- C19orf81 | c.437C>G p.S146W | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1467872749; called by muse, mutect2
- C1QB | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 177/322 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs761255132; called by muse, mutect2, varscan2
- C1orf105 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1283021726; called by muse, mutect2, varscan2
- C7 | c.2028C>G p.S676R | Missense Mutation (SNP) | VAF 321/440 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1332143658; called by muse, mutect2, varscan2
- C7orf31 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs763600669, COSV52218726; called by muse, mutect2, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 160/162 reads (99%) | catalogued as rs753494539; called by mutect2, varscan2
- CDON | c.2941A>G p.M981V | Missense Mutation (SNP) | VAF 246/341 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1437754919; called by muse, mutect2, varscan2
- CEP250 | c.6725G>T p.G2242V | Missense Mutation (SNP) | VAF 265/600 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs949698245; called by muse, mutect2, varscan2
- CLIC5 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 451/451 reads (100%) | SIFT tolerated, low confidence (0.13); catalogued as rs1561909364; called by muse, mutect2, varscan2
- CNTN6 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 12/227 reads (5%) | catalogued as rs1036885374, COSV63164910; called by muse, mutect2
- CPLX4 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as rs1427072503, COSV100231266, COSV55313092; called by muse, mutect2
- CRACD | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs79900113; called by muse, mutect2, varscan2
- CREB3L4 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as rs1384774963; called by muse, mutect2, varscan2
- CSDE1 | c.989G>A p.R330Q (on ENST00000358528 / NM_001007553.3; = p.R299Q on NM_007158.6) | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs777390495, COSV54754094; called by muse, mutect2
- CSMD1 | c.7403G>A p.G2468D (on ENST00000520002; = p.G2467D on NM_033225.6) | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100142023, COSV59328437; called by muse, mutect2, varscan2
- CSMD2 | c.832A>T p.I278F | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs770125222; called by muse, mutect2, varscan2
- DAPK1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 282/405 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs903023243; called by muse, mutect2, varscan2
- DCLK1 | c.2101C>T p.R701C (on ENST00000360631 / NM_001330072.2; = p.D725= on NM_004734.5) | Missense Mutation (SNP) | VAF 118/394 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV55189268; called by muse, mutect2, varscan2
- DMD | c.2863G>T p.V955F | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs1060502657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.4487A>G p.H1496R | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as rs779533493; called by muse, mutect2, varscan2
- DZIP1L | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 111/352 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV100551306; called by muse, mutect2, varscan2
- EBF1 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 161/425 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV58171555, COSV58179214; called by muse, mutect2, varscan2
- EGF | c.3580C>A p.Q1194K | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as COSV54480848; called by muse, mutect2, varscan2
- EMX2 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 230/452 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs758560390; called by muse, mutect2, varscan2
- EPB41L3 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 176/862 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59458840; called by muse, mutect2, varscan2
- EPHA5 | c.3070C>T p.Q1024* | Nonsense Mutation (SNP) | VAF 53/199 reads (27%) | catalogued as COSV99899080; called by muse, mutect2, varscan2
- EYS | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 116/714 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV100676205, COSV100677103; called by muse, mutect2, varscan2
- EYS | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 639/970 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99055046; called by muse, mutect2, varscan2
- FAAP100 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 143/481 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100585691; called by muse, mutect2, varscan2
- FAM160A2 | c.2741G>C p.R914P (on ENST00000449352 / NM_001098794.2; = p.R928P on NM_032127.4) | Missense Mutation (SNP) | VAF 399/552 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.43); catalogued as COSV56414915; called by muse, mutect2, varscan2
- FAM20C | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 113/258 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs1341763536; called by muse, mutect2
- FAM53C | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 585/586 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs1272699882; called by muse, mutect2, varscan2
- FHAD1 | c.2661G>C p.K887N | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV58984889; called by muse, mutect2
- FJX1 | c.1035C>A p.H345Q | Missense Mutation (SNP) | VAF 155/827 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58552360; called by muse, mutect2, varscan2
- FSIP2 | c.4536C>G p.I1512M | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV100556492; called by muse, mutect2, varscan2
- GAP43 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 46/483 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV59343592; called by muse, mutect2
- GAS1 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 321/495 reads (65%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.831); catalogued as rs1477240562; called by muse, mutect2, varscan2
- GCM2 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV65276107; called by muse, mutect2, varscan2
- GK3P | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs754561130; called by muse, mutect2, varscan2
- GPC5 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100992955, COSV100993890; called by muse, mutect2, varscan2
- GPR6 | c.788A>G p.Q263R | Missense Mutation (SNP) | VAF 189/563 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99254238; called by muse, mutect2, varscan2
- GRIA1 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.911); catalogued as COSV53592975; called by muse, mutect2, varscan2
- GRIK4 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 202/300 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1235746638, COSV101483872; called by muse, mutect2, varscan2
- GRM3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 540/918 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV64472708; called by muse, mutect2, varscan2
- HAS1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as rs975764736; called by muse, mutect2
- HCN4 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 162/453 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1046034940; called by muse, mutect2, varscan2
- HEPACAM | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 241/364 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1170806055; called by muse, mutect2, varscan2
- HPCA | c.420G>C p.E140D | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61275819; called by muse, mutect2, varscan2
- IGHV1-24 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs764682950; called by muse, mutect2, varscan2
- IGKV1D-43 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 104/696 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs1389241296; called by muse, mutect2, varscan2
- JAK3 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 205/544 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200202992, COSV71686805; called by muse, mutect2, varscan2
- KCNAB2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs551382529; called by muse, mutect2
- KCNB2 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 149/419 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101578749; called by muse, mutect2, varscan2
- KRTAP15-1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs749763094; called by muse, mutect2
- LILRA2 | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 164/788 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52192203; called by muse, mutect2, varscan2
- LIPI | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 126/184 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV60711069, COSV60715891; called by muse, mutect2, varscan2
- LRRTM3 | c.917A>G p.D306G | Missense Mutation (SNP) | VAF 137/231 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV63672311; called by muse, mutect2, varscan2
- LSM5 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs757373313; called by muse, mutect2, varscan2
- LZTS2 | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64651269; called by muse, mutect2, varscan2
- MAGEC1 | c.2971G>T p.E991* | Nonsense Mutation (SNP) | VAF 139/139 reads (100%) | catalogued as COSV53581450; called by muse, mutect2, varscan2
- MAGI3 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1022016167; called by muse, mutect2, varscan2
- MARCO | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 99/577 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV59057551; called by muse, mutect2, varscan2
- MINPP1 | c.786A>T p.L262F | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.486); catalogued as rs768977489, COSV64354032; called by muse, varscan2
- MOCOS | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 64/310 reads (21%) | catalogued as rs142150953, CM015227, COSV104442038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPL46 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 28/431 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949067402; called by muse, mutect2
- MYH13 | c.2963C>A p.A988E | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs1268534440; called by muse, mutect2, varscan2
- MYO1B | c.2154G>T p.W718C | Missense Mutation (SNP) | VAF 131/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58428006; called by mutect2, varscan2
- NCLN | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 301/598 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99860133; called by muse, mutect2, varscan2
- NDRG1 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 177/513 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60484588; called by muse, mutect2, varscan2
- NDUFAF5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 212/472 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs146962778, COSV104429800; called by muse, mutect2, varscan2
- NF1 | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62211513; called by muse, mutect2
- NOS2 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 226/357 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767806769, COSV100569683; called by muse, mutect2, varscan2
- NPAP1 | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 226/366 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs771047291, COSV61511199; called by muse, mutect2, varscan2
- NTHL1 | c.719C>G p.T240R (on ENST00000219066; = p.T232R on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/397 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54593981; called by muse, mutect2, varscan2
- NTRK3 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV58123580; called by muse, mutect2, varscan2
- OPCML | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 210/324 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762120321, COSV59404700; called by muse, mutect2, varscan2
- OR2B11 | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 454/454 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369166364; called by muse, mutect2, varscan2
- OR4A5 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 40/549 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV60525200; called by muse, mutect2
- OR4K1 | c.916G>T p.V306L | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1207349568, COSV99578950; called by muse, varscan2
- OR4K2 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1412464706, COSV53848982; called by muse, mutect2, varscan2
- OR4K5 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 126/468 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV60003613, COSV60005449; called by muse, mutect2, varscan2
- OR5T3 | c.93T>A p.D31E | Missense Mutation (SNP) | VAF 204/406 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100282728; called by muse, mutect2, varscan2
- OR7G1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 82/173 reads (47%) | catalogued as COSV53318893, COSV53319270; called by muse, mutect2, varscan2
- PANX3 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 278/421 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99421560; called by muse, mutect2, varscan2
- PCDHGC4 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 45/477 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1460090760; called by muse, mutect2
- PCYOX1 | c.418A>G p.K140E | Missense Mutation (SNP) | VAF 203/354 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs780099500; called by muse, mutect2, varscan2
- PEG3 | c.3235C>A p.H1079N | Missense Mutation (SNP) | VAF 540/541 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55636207; called by muse, mutect2, varscan2
- PGLS | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 326/527 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs1438231689; called by muse, mutect2, varscan2
- PHF19 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 44/725 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs770610254, COSV65877599; called by muse, mutect2
- PIEZO2 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 118/1372 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs980975418; called by muse, mutect2
- PLA2G7 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 95/823 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV51259013; called by muse, mutect2, varscan2
- PRDM16 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 396/398 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV54583252; called by muse, mutect2, varscan2
- PRF1 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV64615258; called by muse, mutect2, varscan2
- RAB27B | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 147/187 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1445586376; called by muse, mutect2, varscan2
- RALGAPA2 | c.4273A>G p.N1425D | Missense Mutation (SNP) | VAF 233/459 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs771716711; called by muse, mutect2, varscan2
- RANGAP1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 29/654 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.373); catalogued as rs1363360651, COSV62364116; called by muse, mutect2
- RASIP1 | c.979G>T p.V327L | Missense Mutation (SNP) | VAF 470/471 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs1272802660; called by muse, mutect2, varscan2
- RBM11 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 92/156 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68748409; called by muse, mutect2, varscan2
- REG3G | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV55449665; called by muse, mutect2, varscan2
- RFX4 | c.1097T>C p.M366T (on ENST00000392842 / NM_213594.3; = p.M272T on NM_032491.6) | Missense Mutation (SNP) | VAF 107/338 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs1283917655; called by muse, mutect2, varscan2
- RGS4 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1348516135, COSV63358589; called by muse, mutect2
- RNF183 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 270/407 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs377503602; called by muse, mutect2, varscan2
- SERPINA9 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100098078; called by muse, mutect2, varscan2
- SLC4A4 | c.1203C>A p.D401E (on ENST00000264485 / NM_001098484.3; = p.D357E on NM_003759.4) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1048611954; called by mutect2, varscan2
- SLC6A7 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 41/462 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs757435115; called by muse, mutect2
- SLCO1B3 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 115/169 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs767172087, COSV53946536; called by muse, mutect2, varscan2
- SNPH | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 274/573 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1230589900, COSV67870471; called by muse, mutect2, varscan2
- SP100 | c.2168C>G p.S723C | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV60849867; called by muse, mutect2, varscan2
- SPATA13 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 318/318 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs755337296, COSV57980108; called by muse, mutect2, varscan2
- SPOCD1 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 141/295 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99929662; called by muse, mutect2, varscan2
- SSH1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1434849953; called by muse, mutect2, varscan2
- ST6GAL2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 383/611 reads (63%) | PolyPhen benign (0.017); catalogued as rs762905808, COSV64527943; called by muse, mutect2, varscan2
- STAB2 | c.6613C>T p.P2205S | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV101185868; called by muse, mutect2, varscan2
- STC1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51689389; called by muse, varscan2
- STRA6 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 153/453 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV60589088; called by muse, mutect2, varscan2
- SUZ12 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 105/230 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV100496698; called by muse, mutect2, varscan2
- SYK | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 328/509 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564088424; called by muse, mutect2, varscan2
- TBX22 | c.675C>A p.H225Q | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100960908; called by muse, mutect2, varscan2
- TENM1 | c.3970G>T p.G1324W | Missense Mutation (SNP) | VAF 138/138 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64433918; called by muse, mutect2, varscan2
- THSD7A | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs1387856775, COSV70272861; called by muse, mutect2, varscan2
- TMEM131 | c.3991del p.H1331Tfs*21 | Frame Shift Del (DEL) | VAF 140/617 reads (23%) | catalogued as COSV51780033; called by mutect2, pindel, varscan2
- TMEM156 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV67930021; called by muse, mutect2, varscan2
- TMX4 | c.417A>C p.K139N | Missense Mutation (SNP) | VAF 121/488 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV99851427; called by muse, mutect2, varscan2
- TOP2A | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 129/389 reads (33%) | catalogued as COSV70732740; called by muse, mutect2, varscan2
- TPRA1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 47/566 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs372625321; called by muse, mutect2
- TRIM55 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 225/375 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV52543293; called by muse, mutect2, varscan2
- UNC5A | c.2027C>G p.P676R | Missense Mutation (SNP) | VAF 319/434 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV52845203, COSV99458823; called by muse, mutect2, varscan2
- USH2A | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243877, COSV56435715; called by muse, mutect2, varscan2
- VPS13B | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV62026745; called by muse, mutect2, varscan2
- VWA5B2 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 71/620 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs760764183; called by muse, mutect2, varscan2
- WDR7 | c.2425G>C p.A809P | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54355492, COSV99589482; called by muse, mutect2, varscan2
- WNT11 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 231/638 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490490; called by muse, mutect2, varscan2
- XIRP2 | c.1045A>G p.I349V (on ENST00000628543; = p.I524V on NM_152381.6) | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs1268770993; called by muse, mutect2, varscan2
- ZNF729 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs572428489; called by muse, mutect2, varscan2
- ZNF804A | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV56474495; called by muse, mutect2, varscan2
- ZNF99 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs1461664675; called by muse, mutect2, varscan2
- ZPLD1 | c.547A>G p.T183A (on ENST00000466937 / NM_001329788.1; = p.T199A on NM_175056.2) | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1445325918, COSV60355086; called by muse, mutect2, varscan2
- ZSWIM1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 176/726 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775258001, COSV54845186; called by muse, mutect2, varscan2
- ZXDA | c.1304G>C p.C435S | Missense Mutation (SNP) | VAF 406/407 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs751544967; called by muse, mutect2, varscan2
- ABCA4 | c.4443G>T p.Q1481H | Missense Mutation (SNP) | VAF 310/311 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ABCA8 | c.3749C>A p.A1250E | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.009); called by muse, varscan2
- ACOT13 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 233/233 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACSL1 | c.1522G>C p.V508L | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ACSM5 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 158/236 reads (67%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ACTL7A | c.1182A>C p.E394D | Missense Mutation (SNP) | VAF 288/429 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ADAMTS5 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 131/403 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGB | c.3790A>T p.S1264C | Missense Mutation (SNP) | VAF 114/178 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ADGRE3 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 87/407 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ADGRL4 | c.1487T>A p.L496Q | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADIPOQ | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 93/850 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- AGAP5 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 259/491 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AGBL5 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AK8 | c.1240A>T p.I414F | Missense Mutation (SNP) | VAF 103/342 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ALG1 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 28/682 reads (4%) | called by muse, mutect2
- ALPK3 | c.3988G>C p.A1330P | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- AMY1B | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 137/1600 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AMY1B | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 63/634 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ANKRD34B | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ANKRD36B | c.3176C>G p.S1059* | Nonsense Mutation (SNP) | VAF 222/489 reads (45%) | called by muse, mutect2, varscan2
- ANKRD36C | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 58/552 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ANKRD7 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- AOX1 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ARHGAP30 | c.2581C>T p.L861F | Missense Mutation (SNP) | VAF 190/569 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGAP9 | c.1939C>A p.P647T (on ENST00000393797 / NM_001319850.2; = p.P628T on NM_032496.4) | Missense Mutation (SNP) | VAF 147/472 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF10 | c.1125C>G p.I375M (on ENST00000398564; = p.I350M on NM_014629.4) | Missense Mutation (SNP) | VAF 137/269 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ARHGEF5 | c.4027A>C p.K1343Q | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.285); called by mutect2, varscan2
- ARMC2 | c.2556_2581del p.Q853Pfs*9 | Frame Shift Del (DEL) | VAF 70/344 reads (20%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ARRDC2 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 46/701 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ATP13A5 | c.718T>A p.L240I | Missense Mutation (SNP) | VAF 51/443 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ATP6V0A4 | c.232G>T p.V78F | Missense Mutation (SNP) | VAF 229/637 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- BCL3 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BNC2 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- BRD4 | c.2072G>A p.G691D | Missense Mutation (SNP) | VAF 89/552 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- C1QTNF5 | c.294C>A p.C98* | Nonsense Mutation (SNP) | VAF 408/632 reads (65%) | called by muse, mutect2, varscan2
- C2orf92 | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 219/302 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- C3orf70 | c.487T>C p.S163P | Missense Mutation (SNP) | VAF 173/1013 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1G | c.6245T>G p.V2082G | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, varscan2
- CACNA2D3 | c.3193A>G p.R1065G | Missense Mutation (SNP) | VAF 106/242 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CATSPERE | c.2294T>C p.V765A | Missense Mutation (SNP) | VAF 208/209 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCAR2 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 121/280 reads (43%) | called by muse, mutect2, varscan2
- CCDC15 | c.698A>T p.K233M | Missense Mutation (SNP) | VAF 121/179 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CCDC152 | c.216A>G p.I72M | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC88C | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 281/284 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD109 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CD163 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK9 | c.1118G>C p.*373Sext*56 | Nonstop Mutation (SNP) | VAF 95/270 reads (35%) | called by muse, mutect2, varscan2
- CDYL | c.1502A>T p.E501V (on ENST00000328908 / NM_001368125.1; = p.E447V on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/111 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP170 | c.3230A>T p.K1077M | Missense Mutation (SNP) | VAF 126/449 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP192 | c.2876C>G p.S959* | Nonsense Mutation (SNP) | VAF 34/541 reads (6%) | called by muse, mutect2
- CEP295 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CHRM4 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 132/698 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CLMP | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CLRN3 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CNOT4 | c.1481A>T p.Q494L (on ENST00000315544 / NM_001190848.1; = p.Q491L on NM_013316.4) | Missense Mutation (SNP) | VAF 475/849 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- COL5A2 | c.2528G>A p.G843E | Missense Mutation (SNP) | VAF 179/273 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPA6 | c.1166del p.N389Mfs*37 | Frame Shift Del (DEL) | VAF 24/237 reads (10%) | called by mutect2, pindel
- CPB1 | c.1030A>C p.T344P | Missense Mutation (SNP) | VAF 96/448 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB1 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.2308T>A p.S770T (on ENST00000297405 / NM_001363185.1; = p.S666T on NM_052900.3) | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CSN2 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 258/258 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- CTNNA2 | c.1751G>C p.R584P | Missense Mutation (SNP) | VAF 162/274 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); called by muse, mutect2
- CUL4A | c.2035G>T p.E679* (on ENST00000375440 / NM_001008895.4; = p.E579* on NM_003589.3) | Nonsense Mutation (SNP) | VAF 103/103 reads (100%) | called by muse, mutect2, varscan2
- CWC22 | c.1923T>G p.D641E | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CYLC1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CYP2B6 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 37/714 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.057); called by muse, mutect2
- CYSLTR2 | c.833T>A p.L278* | Nonsense Mutation (SNP) | VAF 247/247 reads (100%) | called by muse, mutect2, varscan2
- DDHD2 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 579/701 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DIAPH1 | c.1756C>G p.P586A | Missense Mutation (SNP) | VAF 441/441 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, varscan2
- DLC1 | c.2246C>A p.T749N (on ENST00000276297 / NM_001348081.2; = p.T312N on NM_006094.5) | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.047); called by muse, mutect2
- DLGAP1 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 186/1786 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DLK1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 405/405 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DNAH10 | c.2479A>T p.I827F (on ENST00000409039; = p.I766F on NM_207437.3) | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- DNAH3 | c.3489C>A p.Y1163* | Nonsense Mutation (SNP) | VAF 92/278 reads (33%) | called by muse, mutect2, varscan2
- DNAH5 | c.7228G>A p.E2410K | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DNAH5 | c.6101T>G p.F2034C | Missense Mutation (SNP) | VAF 87/420 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUOXA1 | c.14del p.G5Dfs*25 | Frame Shift Del (DEL) | VAF 114/364 reads (31%) | called by mutect2, pindel, varscan2
- ENPP2 | c.1851_1856del p.D617_F618del (on ENST00000075322 / NM_001040092.3; = p.D669_F670del on NM_006209.5) | In Frame Del (DEL) | VAF 52/201 reads (26%) | called by mutect2, pindel, varscan2
- ENPP5 | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 506/506 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- EPM2A | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EPPK1 | c.2301C>G p.F767L | Missense Mutation (SNP) | VAF 166/527 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EVA1C | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 118/174 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- FAM111B | c.579G>C p.R193S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM135B | c.1199del p.G400Afs*8 | Frame Shift Del (DEL) | VAF 195/682 reads (29%) | called by mutect2, pindel, varscan2
- FAM20B | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 155/156 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAM210A | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 112/1060 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, mutect2
- FBLL1 | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- FBN2 | c.7624A>T p.N2542Y | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGD4 | c.-245-1G>A | Splice Site (SNP) | VAF 220/312 reads (71%) | called by muse, mutect2, varscan2
- FH | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 323/323 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FYB1 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 117/623 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GADD45GIP1 | c.185C>A p.A62E | Missense Mutation (SNP) | VAF 228/873 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, varscan2
- GBF1 | c.3457G>A p.D1153N (on ENST00000369983 / NM_001377137.1; = p.D1152N on NM_004193.3) | Missense Mutation (SNP) | VAF 160/300 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- GH2 | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 83/410 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GIT1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 193/366 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- GOLGA3 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 215/324 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR158 | c.780G>C p.K260N | Missense Mutation (SNP) | VAF 452/752 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- GRIA4 | c.1424G>T p.R475M | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GRM7 | c.2693C>A p.P898Q | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- GTF2IRD1 | c.2407C>T p.R803W (on ENST00000265755 / NM_016328.3; = p.R788W on NM_005685.4) | Missense Mutation (SNP) | VAF 58/742 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- HECTD4 | c.5717C>T p.P1906L | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR2A | c.190T>G p.S64A | Missense Mutation (SNP) | VAF 133/384 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDH3B | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 294/586 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- IFIH1 | c.398A>T p.D133V | Missense Mutation (SNP) | VAF 250/344 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 318/663 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IL32 | c.18C>A p.V6= | Splice Region (SNP) | VAF 137/455 reads (30%) | called by muse, mutect2, varscan2
- IL37 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 310/407 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IL5RA | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAK1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 123/426 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ISM2 | c.272C>G p.P91R | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ITGA1 | c.1436A>C p.Q479P | Missense Mutation (SNP) | VAF 163/235 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ITGAM | c.1535G>A p.G512E (on ENST00000648685 / NM_001145808.2; = p.G511E on NM_000632.4) | Missense Mutation (SNP) | VAF 297/649 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JHY | c.1458C>A p.H486Q | Missense Mutation (SNP) | VAF 127/215 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- KAT6B | c.4624G>T p.V1542F | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- KCP | c.623C>T p.T208I (on ENST00000620378; = p.T265I on NM_001366122.1) | Missense Mutation (SNP) | VAF 44/1012 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2
- KDM3A | c.2555G>A p.C852Y | Missense Mutation (SNP) | VAF 116/370 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- KIF19 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 319/432 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- KIF25 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 175/507 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- KIF7 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 96/617 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF9 | c.1604C>A p.S535Y | Missense Mutation (SNP) | VAF 182/339 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KLF10 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 35/378 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLHL1 | c.482A>G p.E161G | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KMT2D | c.3307T>A p.C1103S | Missense Mutation (SNP) | VAF 166/363 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KRTAP10-10 | c.664del p.R222Afs*45 | Frame Shift Del (DEL) | VAF 288/431 reads (67%) | called by mutect2, varscan2
- KRTAP3-3 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 607/1029 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LCOR | c.3832C>T p.P1278S | Missense Mutation (SNP) | VAF 127/379 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- LILRA4 | c.1144A>T p.M382L | Missense Mutation (SNP) | VAF 811/816 reads (99%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LINS1 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 28/512 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LPA | c.5509C>T p.L1837F | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRP1B | c.11377G>T p.E3793* | Nonsense Mutation (SNP) | VAF 76/472 reads (16%) | called by muse, mutect2, varscan2
- LRRTM3 | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- LSAMP | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 149/459 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LUZP2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MALRD1 | c.5308G>T p.D1770Y | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K10 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 184/352 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MAVS | c.693_699del p.R232Pfs*69 | Frame Shift Del (DEL) | VAF 115/499 reads (23%) | called by mutect2, pindel, varscan2
- MDN1 | c.10162G>C p.E3388Q | Missense Mutation (SNP) | VAF 137/413 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MDN1 | c.9376G>A p.E3126K | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MINPP1 | c.755del p.F252Sfs*11 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | called by pindel, varscan2
- MLXIPL | c.2272_2274del p.V758del | In Frame Del (DEL) | VAF 107/710 reads (15%) | called by mutect2, pindel, varscan2
- MLXIPL | c.610_611del p.P204* | Frame Shift Del (DEL) | VAF 159/624 reads (25%) | called by mutect2, pindel, varscan2
- MMP2 | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP24 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 312/631 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2633C>A p.S878* | Nonsense Mutation (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- MRC1 | c.2695T>C p.C899R | Missense Mutation (SNP) | VAF 170/433 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MRC1 | c.3125G>A p.R1042K | Missense Mutation (SNP) | VAF 78/365 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- MRTFB | c.2449A>G p.R817G (on ENST00000571589 / NM_001365412.2; = p.R767G on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/428 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- MUC16 | c.35449C>G p.Q11817E | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MYH9 | c.4183G>C p.E1395Q | Missense Mutation (SNP) | VAF 45/795 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2
- MYO1B | c.1322A>C p.N441T | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MYO7A | c.5798C>A p.T1933N | Missense Mutation (SNP) | VAF 136/450 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAA25 | c.2493G>T p.L831F | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NAT16 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 212/1557 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- NCAM2 | c.1271_1272del p.V424Efs*14 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by pindel, varscan2
- NEXMIF | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- NLGN1 | c.2358C>G p.N786K | Missense Mutation (SNP) | VAF 133/854 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- NLRP5 | c.1662A>T p.Q554H | Missense Mutation (SNP) | VAF 124/482 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTNG2 | c.515T>A p.M172K | Missense Mutation (SNP) | VAF 342/556 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- OLFM1 | c.1210del p.E404Rfs*71 (on ENST00000371793 / NM_001282611.2; = p.E386Rfs*71 on NM_014279.5) | Frame Shift Del (DEL) | VAF 210/660 reads (32%) | called by mutect2, pindel, varscan2
- OPA1 | c.1131G>A p.M377I (on ENST00000361510 / NM_130837.3; = p.M322I on NM_015560.3) | Missense Mutation (SNP) | VAF 60/519 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10T2 | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR13C3 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2
- OR2L2 | c.590C>G p.T197R | Missense Mutation (SNP) | VAF 326/327 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- OR4A8 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.28); called by mutect2, varscan2
- OR4K1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- OR4K2 | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR56A3 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT tolerated (0.98); PolyPhen benign (0.012); called by muse, mutect2
- OR5A2 | c.663C>A p.Y221* | Nonsense Mutation (SNP) | VAF 101/327 reads (31%) | called by muse, mutect2, varscan2
- OR6B1 | c.932A>G p.D311G | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6C68 | c.936G>C p.K312N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); called by muse, mutect2
- OR9A4 | c.223A>T p.I75L | Missense Mutation (SNP) | VAF 301/795 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR9H1P | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 462/462 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OVCH1 | c.1143G>C p.L381F | Missense Mutation (SNP) | VAF 103/430 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PACRGL | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PAX1 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 66/848 reads (8%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.006); called by muse, mutect2
- PCDH7 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 253/258 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE2A | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 87/276 reads (32%) | called by muse, mutect2, varscan2
- PDE6C | c.929C>G p.P310R | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN4 | c.2744C>A p.A915D (on ENST00000402685 / NM_001164595.2; = p.A657D on NM_013377.4) | Missense Mutation (SNP) | VAF 173/526 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PHC1 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 151/253 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PIEZO2 | c.6497A>G p.E2166G | Missense Mutation (SNP) | VAF 80/822 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- PIEZO2 | c.6058C>T p.L2020F | Missense Mutation (SNP) | VAF 510/701 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PLEKHA7 | c.3032A>G p.Y1011C | Missense Mutation (SNP) | VAF 107/412 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PLEKHG1 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 126/366 reads (34%) | called by muse, mutect2, varscan2
- PLXNA4 | c.2868_2876del p.S957_L959del | In Frame Del (DEL) | VAF 74/552 reads (13%) | called by mutect2, pindel, varscan2
- PMS2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PNPLA4 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPRC1 | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 194/474 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PYHIN1 | c.276A>C p.K92N | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- RABEP2 | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 362/765 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RABGEF1 | c.103G>T p.G35* (on ENST00000439720 / NM_001287061.2; = p.G22* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 89/667 reads (13%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RASAL1 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- RASGRF1 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RBBP8NL | c.1060del p.A354Hfs*85 | Frame Shift Del (DEL) | VAF 205/840 reads (24%) | called by mutect2, pindel, varscan2
- RBSN | c.2242G>C p.A748P | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RCCD1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 199/575 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RDH8 | c.503-1G>T p.X168_splice (on ENST00000651512; = p.X148_splice on NM_015725.4) | Splice Site (SNP) | VAF 97/207 reads (47%) | called by muse, mutect2, varscan2
- REV3L | c.6427G>A p.D2143N | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- RGPD2 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- RING1 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 60/858 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ROS1 | c.4307T>A p.M1436K | Missense Mutation (SNP) | VAF 197/305 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RRBP1 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 180/364 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.5776G>T p.V1926L | Missense Mutation (SNP) | VAF 595/595 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SAMD9L | c.215A>T p.Y72F | Missense Mutation (SNP) | VAF 404/760 reads (53%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCRIB | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 145/502 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SH3RF3 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 129/685 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- SI | c.3022A>C p.I1008L | Missense Mutation (SNP) | VAF 93/790 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC47A1 | c.333C>A p.H111Q | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SLC47A1 | c.335T>A p.V112E | Missense Mutation (SNP) | VAF 246/247 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A10 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC4A4 | c.1759G>T p.G587C (on ENST00000264485 / NM_001098484.3; = p.G543C on NM_003759.4) | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1C1 | c.607C>G p.P203A | Missense Mutation (SNP) | VAF 28/573 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLTM | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 133/449 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMARCAD1 | c.2492A>G p.H831R | Missense Mutation (SNP) | VAF 110/112 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SMC1B | c.2974G>A p.D992N | Missense Mutation (SNP) | VAF 158/255 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SMG1 | c.9789G>C p.W3263C | Missense Mutation (SNP) | VAF 118/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNED1 | c.2510C>A p.P837H | Missense Mutation (SNP) | VAF 201/408 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNTG1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SPIRE1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 96/971 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.132); called by muse, mutect2
- SPTAN1 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- STAB1 | c.4593C>A p.S1531R | Missense Mutation (SNP) | VAF 141/275 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SUPT20H | c.746A>T p.Q249L (on ENST00000350612 / NM_001014286.3; = p.Q250L on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SURF6 | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 448/738 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- SYNE1 | c.25674G>T p.M8558I (on ENST00000367255 / NM_182961.4; = p.M8510I on NM_033071.3) | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by mutect2, varscan2
- SYNE1 | c.24821C>G p.T8274S (on ENST00000367255 / NM_182961.4; = p.T8203S on NM_033071.3) | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNE1 | c.18902G>A p.S6301N (on ENST00000367255 / NM_182961.4; = p.S6230N on NM_033071.3) | Missense Mutation (SNP) | VAF 137/221 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SYNE1 | c.18730C>A p.Q6244K (on ENST00000367255 / NM_182961.4; = p.Q6173K on NM_033071.3) | Missense Mutation (SNP) | VAF 219/329 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBC1D8 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 95/466 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEKT1 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 137/400 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TGFBRAP1 | c.1983G>T p.Q661H | Missense Mutation (SNP) | VAF 336/411 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- TMEM39A | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNFRSF14 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 305/485 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TRIM39 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 413/414 reads (100%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- TRIM5 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 113/506 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TRIM58 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 547/549 reads (100%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL6 | c.2066C>G p.P689R (on ENST00000393382 / NM_001130918.3; = p.P382R on NM_173623.3) | Missense Mutation (SNP) | VAF 147/443 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TTN | c.30061T>C p.Y10021H (on ENST00000591111; = p.Y9094H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 247/358 reads (69%) | PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.27760G>T p.D9254Y (on ENST00000591111; = p.D8327Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 330/470 reads (70%) | PolyPhen possibly damaging (0.858); called by muse, mutect2
- UBXN7 | c.1080G>C p.E360D | Missense Mutation (SNP) | VAF 72/1018 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- UGGT1 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- UNC5C | c.256_267del p.S86_T89del | In Frame Del (DEL) | VAF 50/146 reads (34%) | called by mutect2, pindel, varscan2
- USP32 | c.3715C>G p.L1239V | Missense Mutation (SNP) | VAF 225/710 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTRN | c.8963A>G p.Q2988R | Missense Mutation (SNP) | VAF 190/284 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VPS50 | c.2111A>G p.E704G | Missense Mutation (SNP) | VAF 131/930 reads (14%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- VPS8 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 86/385 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- VRK1 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 74/74 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WBP11 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 64/166 reads (39%) | called by muse, mutect2, varscan2
- WDFY4 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 135/375 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WDR3 | c.444C>A p.H148Q | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XKR5 | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2
- ZBBX | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 7/191 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2
- ZNF184 | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 366/367 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF32 | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 124/483 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF526 | c.61_66del p.E21_M22del | In Frame Del (DEL) | VAF 98/487 reads (20%) | called by mutect2, pindel, varscan2
- ZNF527 | c.139T>A p.Y47N | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF568 | c.1860G>T p.E620D | Missense Mutation (SNP) | VAF 93/374 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ZNF611 | c.1223C>G p.T408R | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- ZNF639 | c.248A>T p.N83I | Missense Mutation (SNP) | VAF 407/489 reads (83%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF652 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 146/717 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF655 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2
- ZNF672 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 40/947 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ZNF722P | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 94/161 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ZNF836 | c.1299G>C p.Q433H | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- ZSWIM6 | c.2016C>G p.Y672* | Nonsense Mutation (SNP) | VAF 78/159 reads (49%) | called by muse, mutect2, varscan2
- ABCA12 | c.4308G>A p.K1436= (on ENST00000272895 / NM_173076.3; = p.K1118= on NM_015657.3) | Silent (SNP) | VAF 101/218 reads (46%) | catalogued as rs1393235055; called by muse, mutect2, varscan2
- ADCK5 | c.1422G>A p.P474= | Silent (SNP) | VAF 242/873 reads (28%) | catalogued as rs1437436222, COSV58235989; called by muse, varscan2
- ADIPOQ | c.186T>C p.P62= | Silent (SNP) | VAF 93/833 reads (11%) | catalogued as rs375690358, CD093543; called by muse, mutect2, varscan2
- ANO1 | c.1497G>A p.V499= | Silent (SNP) | VAF 89/359 reads (25%) | called by muse, mutect2, varscan2
- AP4M1 | c.111G>C p.L37= | Silent (SNP) | VAF 84/1360 reads (6%) | called by muse, mutect2
- APTX | c.528G>A p.Q176= | Silent (SNP) | VAF 50/204 reads (25%) | called by muse, mutect2, varscan2
- ASXL3 | c.5325C>A p.I1775= | Silent (SNP) | VAF 106/285 reads (37%) | called by muse, mutect2, varscan2
- ATP10A | c.1473G>T p.R491= | Silent (SNP) | VAF 218/600 reads (36%) | catalogued as rs779670138, COSV63514764; called by muse, mutect2, varscan2
- C10orf67 | c.1020C>T p.G340= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- C6orf58 | c.870C>T p.V290= | Silent (SNP) | VAF 29/214 reads (14%) | catalogued as COSV100314688; called by muse, mutect2, varscan2
- C8A | c.1264C>A p.R422= | Silent (SNP) | VAF 268/268 reads (100%) | called by muse, mutect2, varscan2
- CACNA1B | c.3702T>C p.F1234= | Silent (SNP) | VAF 89/326 reads (27%) | catalogued as COSV99498666; called by muse, mutect2, varscan2
- CACNA1I | c.2601G>A p.A867= | Silent (SNP) | VAF 111/387 reads (29%) | catalogued as rs749531032, COSV100361662; called by muse, mutect2, varscan2
- CAMSAP1 | c.3849C>T p.L1283= | Silent (SNP) | VAF 170/537 reads (32%) | catalogued as rs562032561; called by muse, mutect2, varscan2
- CAMSAP1 | c.3591C>T p.L1197= | Silent (SNP) | VAF 354/582 reads (61%) | catalogued as COSV56727499; called by muse, mutect2
- CBLN2 | c.144C>A p.P48= | Silent (SNP) | VAF 82/527 reads (16%) | catalogued as rs759918734, COSV54050210; called by muse, mutect2, varscan2
- CCR2 | c.657C>T p.V219= | Silent (SNP) | VAF 116/253 reads (46%) | called by muse, mutect2, varscan2
- CD300A | c.447A>T p.P149= | Silent (SNP) | VAF 347/461 reads (75%) | called by muse, mutect2, varscan2
- CDK10 | c.879G>A p.S293= (on ENST00000353379 / NM_052988.5; = p.S222= on NM_052987.4) | Silent (SNP) | VAF 169/169 reads (100%) | catalogued as rs1433692754; called by muse, mutect2, varscan2
- CEACAM6 | c.123G>A p.T41= | Silent (SNP) | VAF 136/489 reads (28%) | catalogued as rs782287138, COSV52268117; called by muse, mutect2, varscan2
- CELSR1 | c.7884C>G p.V2628= | Silent (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- CHRM2 | c.1203C>A p.A401= | Silent (SNP) | VAF 333/543 reads (61%) | called by muse, mutect2, varscan2
- CHRM4 | c.504C>T p.I168= | Silent (SNP) | VAF 156/784 reads (20%) | called by muse, mutect2, varscan2
- CLIP2 | c.243G>A p.V81= | Silent (SNP) | VAF 154/1090 reads (14%) | called by muse, mutect2, varscan2
- CLIP2 | c.2700G>A p.Q900= | Silent (SNP) | VAF 116/771 reads (15%) | called by muse, mutect2, varscan2
- CNOT7 | c.138G>C p.V46= | Silent (SNP) | VAF 83/194 reads (43%) | catalogued as rs1360417192; called by muse, mutect2, varscan2
- COA4 | c.210G>A p.A70= | Silent (SNP) | VAF 123/423 reads (29%) | catalogued as rs200528812; called by muse, mutect2, varscan2
- COL14A1 | c.1569T>C p.S523= | Silent (SNP) | VAF 202/324 reads (62%) | called by muse, mutect2, varscan2
- COX4I2 | c.6C>T p.L2= | Silent (SNP) | VAF 24/658 reads (4%) | called by muse, mutect2
- CREBBP | c.207A>G p.Q69= | Silent (SNP) | VAF 89/356 reads (25%) | catalogued as rs1222729071; called by muse, mutect2, varscan2
- CSMD2 | c.2664G>T p.L888= | Silent (SNP) | VAF 298/298 reads (100%) | called by muse, mutect2, varscan2
- DCBLD2 | c.1524A>C p.T508= | Silent (SNP) | VAF 126/221 reads (57%) | called by muse, mutect2, varscan2
- DDAH1 | c.696C>T p.H232= | Silent (SNP) | VAF 109/248 reads (44%) | catalogued as rs555748748, COSV52306677; called by muse, mutect2, varscan2
- DESI1 | c.253C>T p.L85= | Silent (SNP) | VAF 31/555 reads (6%) | called by muse, mutect2
- DNAH5 | c.12135C>G p.L4045= | Silent (SNP) | VAF 376/494 reads (76%) | called by muse, mutect2, varscan2
- DPPA2 | c.615T>C p.C205= | Silent (SNP) | VAF 115/341 reads (34%) | called by muse, mutect2, varscan2
- DST | c.10194T>C p.T3398= | Silent (SNP) | VAF 182/678 reads (27%) | called by muse, mutect2, varscan2
- DST | c.6366C>T p.N2122= | Silent (SNP) | VAF 350/494 reads (71%) | called by muse, varscan2
- EFCAB8 | c.3866G>A p.*1289= | Silent (SNP) | VAF 27/592 reads (5%) | catalogued as rs1022490723; called by muse, mutect2
- EPB41L3 | c.2619G>T p.S873= | Silent (SNP) | VAF 114/1111 reads (10%) | catalogued as rs764952165, COSV59449297, COSV59453657; called by muse, varscan2
- EPB41L3 | c.387C>T p.R129= | Silent (SNP) | VAF 84/446 reads (19%) | called by muse, mutect2, varscan2
- ESRRA | c.93C>T p.T31= | Silent (SNP) | VAF 172/518 reads (33%) | catalogued as rs200261687, COSV50004576, COSV99134409; called by muse, mutect2, varscan2
- FETUB | c.204C>T p.N68= | Silent (SNP) | VAF 66/544 reads (12%) | catalogued as rs756141842; called by muse, mutect2, varscan2
- FOXN1 | c.573T>C p.H191= | Silent (SNP) | VAF 245/521 reads (47%) | catalogued as rs140345611; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMPD3 | c.4806C>A p.T1602= | Silent (SNP) | VAF 217/217 reads (100%) | catalogued as COSV99347323; called by muse, mutect2, varscan2
- GATA3 | c.666C>T p.Y222= | Silent (SNP) | VAF 527/874 reads (60%) | called by muse, mutect2, varscan2
- GOLGA8K | c.1764G>A p.R588= | Silent (SNP) | VAF 339/615 reads (55%) | called by muse, mutect2, varscan2
- GPRIN1 | c.2250G>A p.P750= | Silent (SNP) | VAF 194/717 reads (27%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1335C>G p.V445= | Silent (SNP) | VAF 173/240 reads (72%) | called by muse, mutect2, varscan2
- H1-2 | c.540G>A p.A180= | Silent (SNP) | VAF 33/449 reads (7%) | catalogued as rs773564861, COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2
- HIF1A | c.916A>C p.R306= | Silent (SNP) | VAF 205/205 reads (100%) | called by muse, mutect2, varscan2
- ICAM1 | c.1518G>A p.Q506= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- IRS1 | c.3072G>A p.V1024= | Silent (SNP) | VAF 169/347 reads (49%) | called by muse, mutect2, varscan2
- KCNH7 | c.1596C>G p.L532= | Silent (SNP) | VAF 97/469 reads (21%) | catalogued as COSV59795229, COSV59796958; called by muse, mutect2, varscan2
- KCNK5 | c.120A>T p.T40= | Silent (SNP) | VAF 721/721 reads (100%) | called by muse, mutect2, varscan2
- LAMA1 | c.3048C>T p.C1016= | Silent (SNP) | VAF 124/1302 reads (10%) | catalogued as rs754303766; called by muse, mutect2
- LAMA5 | c.4566G>C p.L1522= | Silent (SNP) | VAF 805/806 reads (100%) | catalogued as rs1230968670; called by muse, mutect2, varscan2
- LIMA1 | c.171C>G p.T57= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as COSV57965743; called by muse, mutect2, varscan2
- MARCO | c.135C>A p.S45= | Silent (SNP) | VAF 103/587 reads (18%) | catalogued as COSV59058949; called by muse, mutect2, varscan2
- MEGF6 | c.3762C>T p.F1254= | Silent (SNP) | VAF 61/411 reads (15%) | catalogued as rs928316466, COSV53890480; called by muse, mutect2, varscan2
- MGAT4B | c.1386G>A p.K462= | Silent (SNP) | VAF 142/544 reads (26%) | called by muse, mutect2, varscan2
- MTMR4 | c.1983T>C p.S661= | Silent (SNP) | VAF 424/694 reads (61%) | called by muse, mutect2, varscan2
- MTR | c.432G>A p.G144= | Silent (SNP) | VAF 20/498 reads (4%) | catalogued as COSV63968303; called by muse, mutect2
- MUC19 | c.186C>A p.G62= | Silent (SNP) | VAF 75/376 reads (20%) | called by muse, mutect2, varscan2
- MUC5B | c.9330C>T p.T3110= | Silent (SNP) | VAF 229/993 reads (23%) | called by muse, mutect2, varscan2
- MUC6 | c.6441C>T p.S2147= | Silent (SNP) | VAF 208/774 reads (27%) | catalogued as rs760884152; called by muse, mutect2, varscan2
- MYO19 | c.2676C>T p.L892= (on ENST00000614623 / NM_001163735.1; = p.L692= on NM_025109.5) | Silent (SNP) | VAF 369/772 reads (48%) | called by muse, mutect2, varscan2
- NIPBL | c.8343T>C p.A2781= | Silent (SNP) | VAF 278/395 reads (70%) | called by muse, mutect2, varscan2
- NOTUM | c.735G>A p.V245= | Silent (SNP) | VAF 297/446 reads (67%) | catalogued as rs1462907169, COSV68826088; called by muse, mutect2, varscan2
- NUDT3 | c.279G>T p.T93= | Silent (SNP) | VAF 180/180 reads (100%) | catalogued as COSV74119148; called by muse, mutect2, varscan2
- NXPH1 | c.462G>A p.R154= | Silent (SNP) | VAF 76/172 reads (44%) | catalogued as rs1294272333; called by muse, mutect2, varscan2
- OR4K1 | c.21G>T p.S7= | Silent (SNP) | VAF 54/216 reads (25%) | catalogued as COSV99578707; called by muse, mutect2
- P2RX1 | c.654C>G p.L218= | Silent (SNP) | VAF 36/612 reads (6%) | catalogued as COSV56652648; called by muse, mutect2
- PARD3B | c.858C>T p.H286= | Silent (SNP) | VAF 110/407 reads (27%) | catalogued as rs570148166, COSV62512680; called by muse, mutect2, varscan2
- PCDHA7 | c.1662C>T p.F554= | Silent (SNP) | VAF 20/738 reads (3%) | catalogued as rs781932623, COSV65347498; called by muse, mutect2
- PCDHGA12 | c.1687C>T p.L563= | Silent (SNP) | VAF 151/569 reads (27%) | catalogued as rs765059815; called by muse, mutect2, varscan2
- PIK3CG | c.714C>T p.D238= | Silent (SNP) | VAF 132/943 reads (14%) | catalogued as rs778266273; called by muse, varscan2
- PIWIL2 | c.531G>A p.P177= | Silent (SNP) | VAF 157/326 reads (48%) | catalogued as rs753622262, COSV63250022; called by muse, mutect2, varscan2
- PIWIL3 | c.333G>A p.K111= | Silent (SNP) | VAF 110/314 reads (35%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.99C>A p.P33= | Silent (SNP) | VAF 178/349 reads (51%) | called by muse, mutect2, varscan2
- PPRC1 | c.45G>A p.P15= | Silent (SNP) | VAF 180/397 reads (45%) | catalogued as COSV99532011; called by muse, mutect2, varscan2
- PRKN | c.367C>T p.L123= | Silent (SNP) | VAF 83/277 reads (30%) | catalogued as rs754066157; called by muse, mutect2, varscan2
- PROM2 | c.1665G>A p.A555= | Silent (SNP) | VAF 48/764 reads (6%) | catalogued as rs149295538; called by muse, mutect2
- PRPF31 | c.717C>A p.T239= | Silent (SNP) | VAF 137/593 reads (23%) | called by muse, mutect2, varscan2
- PRSS16 | c.546C>T p.F182= | Silent (SNP) | VAF 38/586 reads (6%) | catalogued as rs781735908; called by muse, mutect2
- PSMD13 | c.975C>T p.D325= | Silent (SNP) | VAF 108/365 reads (30%) | catalogued as rs575334060, COSV61502010; called by muse, mutect2, varscan2
- RBM17 | c.741C>G p.G247= | Silent (SNP) | VAF 262/443 reads (59%) | called by muse, mutect2, varscan2
- REV1 | c.2040A>G p.Q680= | Silent (SNP) | VAF 32/508 reads (6%) | called by muse, mutect2
- RGS9BP | c.276C>T p.D92= | Silent (SNP) | VAF 338/658 reads (51%) | catalogued as rs770922476; called by muse, mutect2, varscan2
- RNF20 | c.1878C>T p.I626= | Silent (SNP) | VAF 15/196 reads (8%) | called by muse, mutect2
- RNF213 | c.4878G>A p.L1626= | Silent (SNP) | VAF 122/413 reads (30%) | called by muse, mutect2, varscan2
- RORA | c.9A>G p.S3= | Silent (SNP) | VAF 205/347 reads (59%) | called by muse, mutect2, varscan2
- ROS1 | c.5751C>A p.G1917= | Silent (SNP) | VAF 154/499 reads (31%) | called by muse, mutect2, varscan2
- RPAP3 | c.1062C>G p.A354= | Silent (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- SEMA5A | c.3153C>T p.F1051= | Silent (SNP) | VAF 38/258 reads (15%) | called by muse, mutect2, varscan2
- SEPHS1 | c.279A>G p.V93= | Silent (SNP) | VAF 253/445 reads (57%) | called by muse, mutect2, varscan2
- SERPINI2 | c.1014G>A p.E338= | Silent (SNP) | VAF 59/656 reads (9%) | called by muse, mutect2
- SIPA1L1 | c.2883A>G p.L961= | Silent (SNP) | VAF 241/241 reads (100%) | catalogued as rs923695405; called by muse, mutect2, varscan2
- SLC2A12 | c.1263C>A p.P421= | Silent (SNP) | VAF 83/266 reads (31%) | called by muse, mutect2, varscan2
- SLIT3 | c.3294C>T p.C1098= | Silent (SNP) | VAF 24/393 reads (6%) | called by muse, mutect2
- SOX6 | c.594G>C p.L198= | Silent (SNP) | VAF 29/557 reads (5%) | catalogued as COSV57051699; called by muse, mutect2
- SPG7 | c.714G>A p.K238= | Silent (SNP) | VAF 105/105 reads (100%) | called by muse, mutect2, varscan2
- STYXL2 | c.2877A>G p.R959= | Silent (SNP) | VAF 291/292 reads (100%) | called by muse, mutect2, varscan2
- TAS2R1 | c.603G>A p.L201= | Silent (SNP) | VAF 387/496 reads (78%) | called by muse, mutect2, varscan2
- TBL1X | c.582G>A p.T194= | Silent (SNP) | VAF 339/339 reads (100%) | catalogued as rs747724793; called by muse, mutect2, varscan2
- TLL1 | c.1944G>A p.V648= | Silent (SNP) | VAF 197/197 reads (100%) | catalogued as rs754780211; called by muse, mutect2, varscan2
- TNIP2 | c.741G>C p.G247= | Silent (SNP) | VAF 50/554 reads (9%) | called by muse, mutect2
- TOX4 | c.1182G>A p.V394= | Silent (SNP) | VAF 145/279 reads (52%) | called by muse, varscan2
- TRIM51 | c.144T>C p.V48= | Silent (SNP) | VAF 114/492 reads (23%) | called by muse, mutect2, varscan2
- TRMT10C | c.633C>T p.Y211= | Silent (SNP) | VAF 92/385 reads (24%) | catalogued as rs369232636, COSV59305142; called by muse, mutect2, varscan2
- TRUB2 | c.732G>C p.L244= | Silent (SNP) | VAF 20/606 reads (3%) | called by muse, mutect2
- TTN | c.63723T>C p.D21241= (on ENST00000591111; = p.D13817= on NM_003319.4) | Silent (SNP) | VAF 111/464 reads (24%) | called by muse, mutect2, varscan2
- VN1R2 | c.495T>C p.L165= | Silent (SNP) | VAF 99/441 reads (22%) | catalogued as rs534711649; called by muse, mutect2, varscan2
- WDFY4 | c.3012C>A p.S1004= | Silent (SNP) | VAF 155/331 reads (47%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.1755G>T p.V585= | Silent (SNP) | VAF 90/170 reads (53%) | called by muse, mutect2, varscan2
- YY2 | c.108G>A p.P36= | Silent (SNP) | VAF 34/446 reads (8%) | catalogued as rs1178804127, COSV63410656; called by muse, mutect2
- ZDBF2 | c.756G>A p.Q252= | Silent (SNP) | VAF 74/161 reads (46%) | catalogued as COSV65627911; called by muse, mutect2, varscan2
- ZNF214 | c.450T>C p.Y150= | Silent (SNP) | VAF 224/288 reads (78%) | catalogued as rs1469189896; called by muse, mutect2, varscan2
- ZNF316 | c.2745C>T p.Y915= | Silent (SNP) | VAF 200/401 reads (50%) | catalogued as rs916022528; called by muse, varscan2
- ZNF804B | c.468C>A p.G156= | Silent (SNP) | VAF 47/741 reads (6%) | called by muse, mutect2
- ZNF850 | c.2916G>A p.Q972= | Silent (SNP) | VAF 196/412 reads (48%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.1788C>T p.F596= | Silent (SNP) | VAF 63/864 reads (7%) | catalogued as rs143166706; called by muse, mutect2
- AL136439.1 | chr13:27665775 A>G | 3'Flank (SNP) | VAF 450/451 reads (100%) | called by muse, mutect2, varscan2
- CCDC33 | c.1291-11574C>T | Intron (SNP) | VAF 162/473 reads (34%) | catalogued as COSV99173600; called by muse, mutect2, varscan2
- CDC45 | c.542+125T>A | Intron (SNP) | VAF 212/487 reads (44%) | called by muse, mutect2, varscan2
- ETNK1 | c.-255C>G | 5'UTR (SNP) | VAF 108/428 reads (25%) | catalogued as COSV56883845, COSV99861118; called by muse, mutect2, varscan2
- FAM131A | chr3:184338474 G>A | 5'Flank (SNP) | VAF 26/894 reads (3%) | catalogued as rs1362849427, COSV59991118; called by muse, mutect2
- IGFN1 | c.1241+2960G>A | Intron (SNP) | VAF 365/366 reads (100%) | called by muse, mutect2, varscan2
- KIF16B | c.3498+3257C>G | Intron (SNP) | VAF 99/460 reads (22%) | called by muse, mutect2, varscan2
- LINC01583 | n.1315A>G | RNA (SNP) | VAF 106/354 reads (30%) | called by muse, mutect2
- MARCHF1 | c.242+377T>C | Intron (SNP) | VAF 199/199 reads (100%) | called by muse, mutect2, varscan2
- MSRA | c.543+17772C>T | Intron (SNP) | VAF 156/315 reads (50%) | catalogued as rs1231933490; called by muse, mutect2, varscan2
- MYC | c.-544C>G | 5'UTR (SNP) | VAF 187/873 reads (21%) | called by muse, mutect2, varscan2
- OLFM2 | c.*269C>T | 3'UTR (SNP) | VAF 97/208 reads (47%) | called by muse, varscan2
- RABGAP1L | c.1711-89324G>C | Intron (SNP) | VAF 135/135 reads (100%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1429-968G>A | Intron (SNP) | VAF 346/346 reads (100%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2324G>T | Intron (SNP) | VAF 114/115 reads (99%) | catalogued as rs1431457448, COSV57252100; called by muse, mutect2, varscan2
- RPA1 | c.-1C>T | 5'UTR (SNP) | VAF 150/509 reads (29%) | called by muse, mutect2, varscan2
- ZNF688 | c.-497G>C | 5'UTR (SNP) | VAF 39/786 reads (5%) | called by muse, mutect2
